Surgical pathology report (de-identified scan), TCGA case TCGA-R6-A8W5, project TCGA-ESCA (Esophageal Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-R6-A8W5-01B (Primary Tumor).

Specimen Date/Time:

ICD O-3
Adenocarcinoma NOS S140/E
Site ^{with} Esophagus, distal third C15.5
Esophagus NOS C15.9
Q13 3/31/14

DIAGNOSIS

- (A) ESOPHAGUS, MASS, BIOPSY:
INFILTRATING, MODERATELY DIFFERENTIATED ADENOCARCINOMA, ARISING WITH DISTINCTIVE
TYPE BARRETT MUCOSA WITH LOW GRADE COLUMNAR EPITHELIAL DYSPLASIA.

Entire report and diagnosis completed by .

GROSS DESCRIPTION

- (A) ESOPHAGEAL MASS - Multiple tan-pink irregular fragments of tissue (0.6 x 0.2 x 0.2 cm) in aggregate. In toto in A.

CLINICAL HISTORY

Esophageal cancer.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

. These tests have not been

Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 3ecd83f6-3332-4cdd-b59d-4a7845b4f794 (TCGA-R6-A8W5.A43BAAF5-711E-4BFE-BF7F-7EA157F3BEBE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).